CCDI case PBCLEC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/efa2595a-c9a7-4726-b7cf-197c35a87dca

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.1 years (3,678 days).

Biospecimens (3 samples)
- Sample 0DUHGA: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DUHH4, 0DUHI6 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
